Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5119, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5119-01A (Primary Tumor).

FINAL DIAGNOSIS:

KIDNEY, RIGHT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 2 OF 4.
- C. THE CARCINOMA MEASURES 5.7 CM IN GREATEST DIMENSION.
- D. THE CARCINOMA IS CONFINED TO THE KIDNEY.
- E. ALL SURGICAL MARGINS OF RESECTION ARE NEGATIVE FOR CARCINOMA.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. THE NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL INFLAMMATION AND GLOMERULOSCLEROSIS.
- H. TNM PATHOLOGIC STAGE: pT1b NX MX (SEE SYNOPTIC).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Radical nephrectomy
LATERALITY: Right
TUMOR SITE: Upper pole
FOCALITY: Unifocal
TUMOR SIZE: Greatest dimension: 5.7 cm
Additional dimensions: 5.3 x 4.5 cm

MACROSCOPIC EXTENT OF TUMOR:

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G2

PATHOLOGIC STAGING (pTNM): pT1b
pNX
Number of regional lymph nodes examined: 0
pMX

MARGINS:

ADRENAL GLAND: Margins uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION (LVI): Not present

ADDITIONAL PATHOLOGIC FINDINGS: Absent/not identified

INFLAMMATION (type): Chronic interstitial inflammation
GLOMERULAR DISEASE (type): Glomerulosclerosis

KIDNEY-RESIDUAL TUMOR (R): R0

Source: NCI Genomic Data Commons file 60799f84-98b0-49c4-9ebc-02b47fdaf191 (TCGA-B0-5119.D9287B69-0AA3-4BF2-99D6-C0782761DFBB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).